Gene-level copy-number profile of tumor specimen TCGA-AX-A0IU-01A from TCGA case TCGA-AX-A0IU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.6 years (29,063 days).
Specimen TCGA-AX-A0IU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.6100b977-5a8a-40d4-b5d4-829f2bac027a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A0IU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/841e0c37-8f78-4852-8d34-057fb7324845

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,254; copy number 2: 44,336; copy number 3: 7,457; copy number 4: 3,415; copy number 5: 177; copy number 6: 147; copy number 7: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A0IU-01A-11D-A102-01): tumor purity 0.79, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 348 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,691,648–41,242,154, 15 genes, copy number 6 (within-gene range 3–6): NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1, AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1, SCMH1, RPL23AP17.
- chr1:233,288,868–233,385,148, 3 genes, copy number 5: RPS7P3, AL133380.1, MAP3K21.
- chr2:15,591,178–15,744,339, 3 genes, copy number 5: DDX1, AC008278.1, LINC01804.
- chr2:25,926,598–26,827,520, 26 genes, copy number 5 (within-gene range 4–5): KIF3C, UQCRHP2, TRMT112P6, RAB10, RNU6-942P, RPS2P15, EMP2P1, SMARCE1P6, AC011742.1, PPIL1P1, GAREM2, HADHA, HADHB, AC010896.1, ADGRF3, SELENOI, DRC1, OTOF, FAM166C, CIB4, AC015977.1, RPL37P11, KCNK3, SLC35F6, CENPA, CDKN2AIPNLP2.
- chr2:27,253,684–28,426,719, 42 genes, copy number 5 (within-gene range 4–5): SLC30A3, DNAJC5G, TRIM54, UCN, MPV17, GTF3C2, GTF3C2-AS1, AC074117.1, EIF2B4, SNX17, ZNF513, PPM1G, FTH1P3, NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P, FNDC4, GCKR, C2orf16, ZNF512, AC074091.2, CCDC121, GPN1, AC074091.1, SUPT7L, SLC4A1AP, LINC01460, MRPL33, RBKS, BABAM2, MYG1P1, MIR4263, FAM133EP, AC096552.1, AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2.
- chr2:64,578,892–65,056,168, 15 genes, copy number 5: RNU6-100P, LINC02579, SERTAD2, AC007365.1, RPS10P9, RN7SL341P, Y_RNA, AC007880.1, LINC01800, LINC02245, RN7SL211P, RPL11P1, SLC1A4, RNU6-548P, LINC02576.
- chr2:69,457,997–70,103,220, 15 genes, copy number 5 (within-gene range 4–5): AAK1, RN7SL604P, SNORA36C, RPL36AP16, B3GALNT1P1, ANXA4, AC092431.1, GMCL1, AC019206.1, RPL23AP92, SNRNP27, MXD1, ASPRV1, PCBP1-AS1, RN7SL470P.
- chr2:73,892,314–74,778,780, 55 genes, copy number 6 (within-gene range 4–6): ACTG2, DGUOK, DGUOK-AS1, RNA5SP97, AC073046.1, TET3, AC110801.1, FNBP1P1, AC073263.1, BOLA3, BOLA3-AS1, MOB1A, MTHFD2, AC073263.3, AC073263.2, AC006030.1, SLC4A5, KRT18P26, RNU6-542P, NECAP1P2, TAF13P2, DCTN1, DCTN1-AS1, AC005041.1, AC005041.2, C2orf81, AC005041.4, HMGA1P8, WDR54, RTKN, INO80B, INO80B-WBP1, WBP1, MOGS, AC005041.5, MRPL53, CCDC142, TTC31, LBX2, AC005041.3, LBX2-AS1, PCGF1, TLX2, DQX1, AUP1, HTRA2, LOXL3, DOK1, M1AP, TOR1BP1, TVP23BP2, SEMA4F, AC007387.2, RPS28P5, AC007387.1.
- chr10:29,289,061–29,487,745, 4 genes, copy number 5 (within-gene range 3–5): LYZL1, AL158167.1, SVIL-AS1, PTCHD3P1.
- chr10:100,735,603–101,137,789, 17 genes, copy number 5: PAX2, Y_RNA, AL138762.1, SLF2, AL133215.3, MRPL43, SEMA4G, MIR608, AL133215.1, TWNK, LZTS2, PDZD7, SFXN3, AL133215.2, KAZALD1, TLX1NB, TLX1.
- chr11:34,915,829–35,918,739, 19 genes, copy number 5: PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1.
- chr17:38,530,031–39,154,394, 39 genes, copy number 6 (within-gene range 3–6): SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440, PCGF2, AC006449.5, PSMB3, RNU6-866P, PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21, AC110749.1, LASP1, AC006441.1, MIR6779, AC006441.3, LINC00672, FBXO47, AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2.
- chr20:2,692,874–3,707,128, 33 genes, copy number 5: EBF4, RPL19P1, CPXM1, AL035460.1, C20orf141, TMEM239, PCED1A, VPS16, PTPRA, GNRH2, MRPS26, OXT, AVP, RN7SL555P, UBOX5-AS1, UBOX5, FASTKD5, LZTS3, DDRGK1, ITPA, SLC4A11, AL109976.1, C20orf194, RNU6-1019P, UBE2V1P1, U3, AL117334.1, AL353193.1, ATRN, SF3A3P1, GFRA4, ADAM33, SIGLEC1.
- chr20:36,651,766–37,241,619, 14 genes, copy number 7 (within-gene range 4–7): NDRG3, Y_RNA, DSN1, SOGA1, RN7SL156P, TLDC2, SAMHD1, RBL1, RPS3AP3, RPS27AP3, AL136172.1, MROH8, AL031659.1, RPN2.
- chr20:47,209,214–47,656,877, 10 genes, copy number 7 (within-gene range 4–7): ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1.
- chr20:50,081,124–50,429,483, 12 genes, copy number 6: UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P.
- chr20:57,105,741–57,960,176, 26 genes, copy number 6: AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1.

Autosomal genes at a single copy (total copy number 1): 4,254. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
